Surgical pathology report (de-identified scan), TCGA case TCGA-R5-A805, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R5-A805-01A (Primary Tumor).

[page 1 of 3]
~~CSCF~~ ICD-O-3
Adenocarcinoma, intestinal type
~~path~~ 8144/3
Adenocarcinoma NOS 8140/3
~~CSCF~~
Site: gastroesophageal junction
~~path~~ C16.0
Distal third esophagus C15.5
9/10/13

Specimen Date/Time:

DIAGNOSIS

- (A) STOMACH, DISTAL CURVATURE, 35 CM, BIOPSY:
Oxyntic/fundic mucosa with focal acellular mucin and inactive chronic gastritis.
No viable tumor or Helicobacter pylori (H&E stain) identified.
- (B) ESOPHAGUS, TUMOR AT 39 CM, BIOPSY:
INFILTRATING, MODERATE TO POORLY DIFFERENTIATED ADENOCARCINOMA WITH SEPARATE
FRAGMENT OF CARDIAC TYPE MUCOSA.
No distinctive type Barrett mucosa identified.
- (C) ESOPHAGUS, DISTAL, BIOPSY:
INFILTRATING, MODERATE TO POORLY DIFFERENTIATED ADENOCARCINOMA WITH OVERLYING
SQUAMOUS EPITHELIUM.
No non-neoplastic columnar epithelium identified.

Entire report and diagnosis completed by

GROSS DESCRIPTION

- (A) DISTAL CURVATURE, 35 CM - Multiple tan-pink irregular fragments of tissue (1.2 x 0.7 x 0.3 cm in aggregate). Toto in A.
- (B) TUMOR AT 39 CM - Three tan-pink irregular fragments of tissue (0.2 x 0.2 x 0.2 through 0.4 x 0.3 x 0.1 cm). Toto in B.
- (C) DISTAL ESOPHAGUS, RULE OUT BARRETT'S AND CANCER - Two white-pink irregular fragments of tissue (0.3 x 0.2 x 0.1 and 0.2 x 0.2 x 0.1 cm). Toto in C.

CLINICAL HISTORY

Esophageal cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

-----END OF REPORT-----

[page 2 of 3]
Specimen Date/Time:

Per TSS, dx discrepancy from
status TEGA tumor to be
intestinal adenocarcinoma, NOS.

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:

Person ID: N/A

Study/Site: TCGA Stomach adenocarcinoma - adenocarcinoma)

(Stomach

Age: N/A

Event: PathDiscrepancy

Date of Birth:

Interviewer:

Sex: M

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report MODERATE TO POORLY DIFFERENTIATED ADENOCARCINOMA

Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF Intestinal Adenocarcinoma Type Not Otherwise Specified (NOS)

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form The pathologists at always use the gastric cancer classification as intestinal and diffuse (which is so as per TCGA).

do not Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file 385e67ee-0ddc-4aac-b5d0-c387a27ca420 (TCGA-R5-A805.448B7322-380F-4C62-B428-C78428AC43F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).